Surgical pathology report (de-identified scan), TCGA case TCGA-06-0749, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0749-01A (Primary Tumor).

[page 1 of 4]
TCGA-06-0749

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] with past history of migraine headaches and small strokes, has a large right temporal necrotic tumor with irregular enhancement and restricted central diffusion.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Right temporal brain tumor
B: Brain, excision biopsy
C: Brain, medial and inferior temporal, excision biopsy
D: Brain, posterior margin, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, C, and D: Brain, temporal lobe, excision:

1. Glioblastoma.
2. MIB-1 proliferation index: 22%.
- See Microscopy Description and Comment.

COMMENT

In all the specimens there is a glial neoplastic proliferation that extensively infiltrates and focally effaces the cerebral tissue. The neoplasm has anaplastic features, i.e. nuclear atypia, mitotic activity, microvascular cellular proliferation, and zones of necrosis with vascular thrombosis. Focally, the tumor has extensively infiltrated the leptomeningeal space.

The neoplasm has a predominantly astrocytic phenotype, but in some infiltrative areas there is a capillary vascular network with focal mineralization. This feature suggests an oligodendroglial component.

This neoplasm may probably be better classified as a glioblastoma, with possibly an oligodendroglial component (WHO IV/IV).

The neoplasm is present in all specimens. In specimen D ("posterior"), the tumor is only moderately cellular and is devoid of necrosis.

Molecular-genetic data may better characterize this tumor.

PROCEDURES/ADDENDA

[page 2 of 4]
MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing was done on block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S1592, D1S468, D1S1612, D1S496, D19S412, PLA2G4C, D19S606, D19S1182

Results-Comments

Test performed on paraffin tumor block ' [REDACTED] and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in

[page 3 of 4]
[REDACTED]

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Right temporal brain tumor:

1. Touch prep and smears: Spindle cell neoplasm, glial.
2. Frozen section: Glioma, infiltrative, with anaplastic features (gross necrosis and imaging studies C/W high grade glioma).

[REDACTED] Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.

Received fresh, two portions of cerebrum; one is falciform, 6.5 x 2.0 x 1.5 cm, and consists of cerebral cortex and adjacent white matter that appear to surround a central cystic cavity; the lesional tissue obliterates land marks, and is semi firm, homogeneous, and gray-glistening; The other fragment is somewhat lobulated, purplish-grey, and homogeneously glistening. Representative sections, A1-A3, frozen tissue A4.

B.

Received fresh, one fragment, 2.0 cm. across. Semi firm, creamy-white. In total, B1 and B2.

C.

SPECIMEN: Medial and inferior temporal.

FIXATIVE: None.

GENERAL: Received is a 4.5 x 3 x 1.5 cm. aggregate of semi-firm homogeneous, gray-tan hemorrhagic glistening soft tissue. Arborizing vessels are identified on some of the surfaces. Sectioning reveals gray-white fleshy cut surfaces.

SECTIONS: Entirely submitted in five cassettes.

D.

SPECIMEN: Posterior.

FIXATIVE: None.

GENERAL: Received is a 4.5 x 3.5 x 1.2 cm. aggregate of semi-firm homogeneous tan-gray glistening, hemorrhagic soft tissue fragments. Sectioning reveals pale gray-white fleshy glistening cut surfaces.

SECTIONS: Entirely submitted in five cassettes.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates overall gliofibrillogenesis by the neoplastic cells, with focal areas of sparse glial background. The tumor cells do not over express the p53 protein. With the MIB-1 there is a proliferation index of about 22% in the more active areas. The NeuN depicts neurons in the infiltrated cerebral cortex. The NFP demonstrates a handful of cortical neurons containing perikaryal phosphorylated NFP, but these cells are not morphologically atypical. The CD163 depicts a large population of

[page 4 of 4]
positive cells, some with granular cytoplasm.

The immunophenotype is consistent with a high histological grade, predominantly astrocytic glioma.

ICD-9(s):

239.6 239.6

Histo Data

Part A: Right temporal brain tumor

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	
H/E x 1	4	[REDACTED]	
H/E x 1	5	[REDACTED]	

Part B: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	

Part C: Brain, medial and inferior temporal, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	
H/E x 1	4	[REDACTED]	
H/E x 1	5	[REDACTED]	

Part D: Brain, posterior margin, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	
H/E x 1	4	[REDACTED]	
CD163 Vector x 1	5	[REDACTED]	
mGFAP-DA x 1	5	[REDACTED]	
H/E x 1	5	[REDACTED]	
MIB1-DA x 1	5	[REDACTED]	
NeuN x 1	5	[REDACTED]	
NF2F11 x 1	5	[REDACTED]	
P53DO7 x 1	5	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 4beb8152-6c07-4b18-971e-f8b65daf5581 (TCGA-06-0749.30421CAA-B781-4140-97FF-5EDE12ED288D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).